Somatic mutation profile of cancer-model specimen HCM-CSHL-1268-C24-85M (3D Organoid; aliquot HCM-CSHL-1268-C24-85M-01D-A882-36), derived from the metastatic tumor of HCMI case HCM-CSHL-1268-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 58.9 years (21,495 days).
Specimen HCM-CSHL-1268-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1811266-54df-4693-99c7-8b6be7a5dee2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1268-C24-11A (Solid Tissue Normal), aliquot HCM-CSHL-1268-C24-11A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a45eddd9-e738-40ca-9125-aa96913c2b4f

The open-access MAF lists 2,173 somatic variants for this specimen: 1,606 protein-altering or splice-affecting, 485 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,124, Silent 485, Frame Shift Del 334, Frame Shift Ins 60, Intron 52, Nonsense Mutation 49, In Frame Del 13, Splice Region 11, 5'UTR 9, Splice Site 9, 3'UTR 8, 5'Flank 6.

Variants (750 of 2,173; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAAS | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 148/312 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758440592, CM055898, CM065946, COSV52932932; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMS1 | c.2789G>A p.R930H | Missense Mutation (SNP) | VAF 168/339 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777706, CM136119; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1922A>C p.K641T (on ENST00000288602 / NM_001374244.1; = p.K601T on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 137/328 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs397507484, CM123147, CM140993, COSV56070869, COSV56115928; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 140/304 reads (46%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- COL4A3 | c.4486C>T p.R1496* | Nonsense Mutation (SNP) | VAF 160/406 reads (39%) | catalogued as rs769863513, CM052202, COSV67420825; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DAXX | c.1178del p.K393Rfs*135 | Frame Shift Del (DEL) | VAF 318/1143 reads (28%) | catalogued as rs1359674497; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- FGD1 | c.527del p.P176Hfs*39 | Frame Shift Del (DEL) | VAF 110/128 reads (86%) | catalogued as rs756586058; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.99T>A p.D33E | Missense Mutation (SNP) | VAF 152/324 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV55525725, COSV55810858; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 201/568 reads (35%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.7219C>T p.R2407* | Nonsense Mutation (SNP) | VAF 181/417 reads (43%) | catalogued as rs398124471, CM073232, COSV56956936; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 214/223 reads (96%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, varscan2
- RBCK1 | c.1054C>T p.R352* (on ENST00000356286 / NM_031229.4; = p.R310* on NM_006462.6) | Nonsense Mutation (SNP) | VAF 120/323 reads (37%) | catalogued as rs780854072, CM1313364, COSV100675876; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4943G>A p.R1648H (on ENST00000303395 / NM_001202435.3; = p.R1637H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 241/540 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918622, CM000570; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 92/224 reads (41%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 169/405 reads (42%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- VPS13B | c.5295G>T p.E1765D | Missense Mutation (SNP) | VAF 106/326 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs780598553, CS125684, COSV100661925; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.342dup p.Q115Tfs*3 | Frame Shift Ins (INS) | VAF 101/176 reads (57%) | catalogued as rs376463919; called by mutect2, varscan2
- ABCA1 | c.1978G>A p.V660M | Missense Mutation (SNP) | VAF 218/474 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762093692, COSV66066034; called by muse, mutect2, varscan2
- ABI3 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 199/460 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs774034002, COSV56800665; called by muse, mutect2, varscan2
- ABTB2 | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 280/570 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1475186898, COSV54395688; called by muse, mutect2, varscan2
- ACAN | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 354/781 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs749720584, COSV61368045; called by muse, mutect2, varscan2
- ACOT7 | c.355G>A p.G119S (on ENST00000377855 / NM_181864.3; = p.G109S on NM_007274.4) | Missense Mutation (SNP) | VAF 264/530 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1257929224; called by muse, mutect2, varscan2
- ADAMTS2 | c.2368G>A p.A790T | Missense Mutation (SNP) | VAF 267/586 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as COSV52393830; called by muse, mutect2, varscan2
- ADAMTS2 | c.2191del p.R731Gfs*26 | Frame Shift Del (DEL) | VAF 152/382 reads (40%) | catalogued as COSV52364596; called by mutect2, pindel, varscan2
- ADAMTS2 | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 35/534 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1427715074; called by muse, mutect2
- ADAMTS5 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 147/292 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53176252; called by muse, mutect2, varscan2
- ADCY10 | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 216/479 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373573088; called by muse, mutect2, varscan2
- ADGRB1 | c.4168G>A p.A1390T | Missense Mutation (SNP) | VAF 141/502 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1239694222; called by muse, mutect2, varscan2
- ADGRF5 | c.2485G>A p.V829M | Missense Mutation (SNP) | VAF 204/570 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1254299103; called by muse, mutect2, varscan2
- ADGRL1 | c.2453C>A p.T818N (on ENST00000340736 / NM_001008701.3; = p.T813N on NM_014921.5) | Missense Mutation (SNP) | VAF 302/547 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1187677025; called by muse, mutect2, varscan2
- ADRA1A | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 266/840 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV52368465; called by muse, mutect2, varscan2
- ADRA2C | c.1096A>C p.S366R | Missense Mutation (SNP) | VAF 209/419 reads (50%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.827); catalogued as rs764347832; called by mutect2, varscan2
- AFAP1L2 | c.1640T>G p.L547R | Missense Mutation (SNP) | VAF 290/576 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as rs776740763; called by muse, mutect2
- AGBL2 | c.2678A>G p.Y893C | Missense Mutation (SNP) | VAF 239/496 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs748126466; called by muse, mutect2, varscan2
- AKAP6 | c.4613G>A p.R1538H | Missense Mutation (SNP) | VAF 203/473 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs539925484, COSV55207514; called by muse, mutect2, varscan2
- AKNAD1 | c.1759G>A p.G587S | Missense Mutation (SNP) | VAF 186/384 reads (48%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs370337411; called by muse, varscan2
- ALMS1 | c.8541G>T p.M2847I | Missense Mutation (SNP) | VAF 19/527 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs1183007080; called by muse, mutect2
- ALOX15 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 224/510 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1473044691; called by muse, mutect2, varscan2
- ALPK3 | c.4313C>T p.S1438L | Missense Mutation (SNP) | VAF 322/657 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775335205, COSV51930604; called by muse, mutect2, varscan2
- AMFR | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 314/654 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs747167232; called by muse, mutect2, varscan2
- AMPH | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 147/349 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100342210; called by muse, mutect2, varscan2
- ANGPTL6 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 253/528 reads (48%) | catalogued as rs201518909; called by muse, mutect2, varscan2
- ANKRD17 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 190/417 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs770504687, COSV58216064; called by muse, mutect2, varscan2
- ANKRD18A | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs547528389, COSV68804269; called by muse, mutect2, varscan2
- ANKRD18B | c.853del p.R285Efs*4 | Frame Shift Del (DEL) | VAF 110/255 reads (43%) | catalogued as rs755445457; called by mutect2, varscan2
- ANKRD6 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 122/371 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs200814043; called by muse, varscan2
- ANO9 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 203/414 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as rs542936963, COSV60448403; called by muse, mutect2, varscan2
- ANTXR1 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 221/422 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV58019953; called by muse, mutect2, varscan2
- AP002748.5 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 306/615 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs1368997318; called by muse, mutect2, varscan2
- AP3M2 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 203/620 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as rs770525839; called by muse, mutect2, varscan2
- APC | c.3242G>A p.S1081N | Missense Mutation (SNP) | VAF 204/416 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs374380039, COSV57399738; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOE | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 339/671 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.842); catalogued as rs947015878, COSV99376338; called by muse, mutect2, varscan2
- APTX | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 130/266 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs762632610; called by muse, mutect2, varscan2
- AQP5 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 264/549 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52231082; called by muse, mutect2, varscan2
- AQP8 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 196/420 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as rs1407897720; called by muse, mutect2, varscan2
- AR | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 290/290 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.253); catalogued as rs751758551; called by muse, mutect2, varscan2
- ARHGAP11A | c.2229G>A p.M743I | Missense Mutation (SNP) | VAF 28/651 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1344384732; called by muse, mutect2
- ARHGAP23 | c.2131G>A p.G711S | Missense Mutation (SNP) | VAF 155/287 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.409); catalogued as rs1254539950; called by muse, mutect2, varscan2
- ARHGAP24 | c.136del p.D46Ifs*42 | Frame Shift Del (DEL) | VAF 218/526 reads (41%) | catalogued as COSV67846950; called by mutect2, pindel, varscan2
- ARHGAP26 | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 200/591 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1433108180; called by muse, mutect2, varscan2
- ARHGEF7 | c.67dup p.T23Nfs*86 (on ENST00000375741 / NM_001113511.2; = p.T23Nfs*65 on NM_145735.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 218/418 reads (52%) | catalogued as rs754827718; called by mutect2, varscan2
- ARSJ | c.1292del p.N431Mfs*86 | Frame Shift Del (DEL) | VAF 206/474 reads (43%) | catalogued as rs1562327720; called by mutect2, varscan2
- ASCC3 | c.1058del p.K353Rfs*6 | Frame Shift Del (DEL) | VAF 170/615 reads (28%) | catalogued as rs1361297712; called by mutect2, pindel, varscan2
- ASCC3 | c.489dup p.G164Wfs*2 | Frame Shift Ins (INS) | VAF 145/492 reads (29%) | catalogued as rs747570359; called by mutect2, varscan2
- ASL | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs201352504; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- ASPHD2 | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 286/639 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV53218932; called by muse, mutect2, varscan2
- ASTN2 | c.2683T>C p.S895P (on ENST00000313400 / NM_001365069.1; = p.S844P on NM_014010.5) | Missense Mutation (SNP) | VAF 222/476 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV57774733; called by muse, mutect2, varscan2
- ASXL2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 278/530 reads (52%) | catalogued as COSV55453315, COSV55459595; called by muse, mutect2, varscan2
- ATAD2 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 181/548 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs200021152; called by muse, mutect2, varscan2
- ATCAY | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 238/500 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs770582696, COSV100008582; called by muse, mutect2, varscan2
- ATG9A | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs968964555; called by muse, mutect2
- ATN1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 251/508 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs782316240; called by muse, mutect2, varscan2
- ATP2A3 | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 238/500 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765464068; called by muse, mutect2, varscan2
- ATP6V1F | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 293/592 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs145784230; called by muse, mutect2, varscan2
- ATP9B | c.1032T>C p.G344= | Splice Region (SNP) | VAF 111/260 reads (43%) | catalogued as COSV56957712; called by muse, mutect2, varscan2
- ATXN1 | c.1882G>A p.V628M | Missense Mutation (SNP) | VAF 179/620 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs377356058; called by muse, mutect2, varscan2
- ATXN2L | c.2584C>A p.P862T | Missense Mutation (SNP) | VAF 201/394 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV100294693; called by muse, mutect2, varscan2
- ATXN7 | c.2213G>A p.C738Y | Missense Mutation (SNP) | VAF 278/598 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1048571039; called by muse, mutect2, varscan2
- ATXN7L1 | c.2547G>T p.Q849H | Missense Mutation (SNP) | VAF 211/399 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as rs1487481516, COSV66300450; called by muse, mutect2, varscan2
- AXIN1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 178/368 reads (48%) | catalogued as COSV51995526; called by muse, mutect2, varscan2
- B3GNT6 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 127/742 reads (17%) | catalogued as rs1555027670; called by muse, mutect2, varscan2
- B3GNT9 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 305/660 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99531342; called by muse, mutect2, varscan2
- BACH1 | c.432del p.K144Nfs*22 | Frame Shift Del (DEL) | VAF 160/474 reads (34%) | catalogued as rs748639705; called by mutect2, pindel, varscan2
- BACH2 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 219/767 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57600126; called by muse, mutect2, varscan2
- BAIAP2 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 174/407 reads (43%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs764303213, COSV58373796; called by muse, mutect2, varscan2
- BAIAP2L2 | c.770del p.P257Rfs*31 | Frame Shift Del (DEL) | VAF 110/261 reads (42%) | catalogued as rs1402946746; called by mutect2, pindel, varscan2
- BARD1 | c.1418A>C p.H473P | Missense Mutation (SNP) | VAF 141/287 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176328026, COSV53612807; ClinVar: uncertain significance; called by muse, varscan2
- BARD1 | c.858A>G p.I286M | Missense Mutation (SNP) | VAF 184/389 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.275); catalogued as rs772845446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ2A | c.3691G>A p.A1231T | Missense Mutation (SNP) | VAF 27/551 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1196211547; called by muse, mutect2
- BBOX1 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 191/419 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV54193858; called by muse, mutect2, varscan2
- BCAS2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 120/278 reads (43%) | catalogued as rs781038404; called by muse, mutect2, varscan2
- BCKDK | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 147/324 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs781670286; called by muse, mutect2, varscan2
- BCS1L | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 270/527 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs754414354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BEND3 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 276/848 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs781925980; called by muse, mutect2, varscan2
- BEND5 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 305/600 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV65718687; called by muse, mutect2, varscan2
- BIRC6 | c.5488C>T p.R1830W | Missense Mutation (SNP) | VAF 173/380 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70204050; called by muse, mutect2, varscan2
- BIRC6 | c.7319C>T p.A2440V | Missense Mutation (SNP) | VAF 177/398 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.193); catalogued as rs1298167873; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 166/359 reads (46%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BOD1L2 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 248/479 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV101649296; called by muse, varscan2
- BOP1 | c.106dup p.L36Pfs*34 | Frame Shift Ins (INS) | VAF 146/515 reads (28%) | catalogued as rs782133829; called by mutect2, varscan2
- BSN | c.9338G>A p.R3113H | Missense Mutation (SNP) | VAF 352/723 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs140240631; called by muse, mutect2, varscan2
- BTN3A3 | c.650del p.G217Vfs*74 | Frame Shift Del (DEL) | VAF 248/880 reads (28%) | catalogued as rs1387186083; called by mutect2, pindel, varscan2
- C1orf141 | c.363del p.K121Nfs*12 | Frame Shift Del (DEL) | VAF 94/214 reads (44%) | catalogued as rs145606616, COSV63992899; called by mutect2, varscan2
- C4orf50 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 293/600 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423092488; called by muse, mutect2, varscan2
- C6orf132 | c.1344dup p.S449Qfs*63 | Frame Shift Ins (INS) | VAF 156/510 reads (31%) | catalogued as rs774701362; called by mutect2, varscan2
- C6orf132 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 329/983 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs1275712359; called by muse, varscan2
- CACTIN | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 283/551 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs889092455, COSV50269608; called by muse, mutect2, varscan2
- CALCOCO1 | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 221/430 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); catalogued as COSV100017509; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 165/348 reads (47%) | catalogued as rs1375954479; called by mutect2, varscan2
- CAPN2 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 283/583 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs746607443; called by muse, mutect2, varscan2
- CAPN6 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 266/266 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs760708333; called by muse, mutect2, varscan2
- CAPNS1 | c.242del p.P81Rfs*41 | Frame Shift Del (DEL) | VAF 202/429 reads (47%) | catalogued as COSV55822800; called by mutect2, pindel, varscan2
- CARNS1 | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 233/477 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1268865987; called by muse, mutect2, varscan2
- CBX2 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 330/677 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782480335, COSV53969493; called by muse, mutect2, varscan2
- CCDC149 | c.1002dup p.L335Ifs*39 (on ENST00000635206 / NM_001330643.2; = p.L335Ifs*28 on NM_173463.5) | Frame Shift Ins (INS) | VAF 144/334 reads (43%) | catalogued as rs1478034807; called by mutect2, varscan2
- CCDC168 | c.15500C>T p.S5167L | Missense Mutation (SNP) | VAF 196/444 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs555882008, COSV59420393; called by muse, varscan2
- CCDC17 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 195/414 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as rs746935513, COSV100601957; called by muse, mutect2, varscan2
- CCDC185 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 271/580 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as rs138878151, COSV64820216, COSV64820505; called by muse, mutect2, varscan2
- CCDC42 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 290/620 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs142451736; called by muse, mutect2, varscan2
- CCDC6 | c.44del p.G15Afs*59 | Frame Shift Del (DEL) | VAF 287/687 reads (42%) | catalogued as COSV99569582; called by mutect2, pindel, varscan2
- CCDC62 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 120/263 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs755321849; called by muse, mutect2, varscan2
- CCDC9 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 175/381 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1390076894; called by muse, mutect2, varscan2
- CCR1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 187/432 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.586); catalogued as rs181920971; called by muse, mutect2, varscan2
- CD109 | c.743del p.G248Vfs*13 | Frame Shift Del (DEL) | VAF 120/466 reads (26%) | catalogued as COSV99753404; called by mutect2, pindel, varscan2
- CDC42BPG | c.3784G>T p.A1262S | Missense Mutation (SNP) | VAF 400/825 reads (48%) | SIFT tolerated (0.85); PolyPhen benign (0.019); catalogued as rs1410637516; called by muse, mutect2, varscan2
- CDH15 | c.1162del p.A388Hfs*89 | Frame Shift Del (DEL) | VAF 309/855 reads (36%) | catalogued as COSV99228980; called by mutect2, pindel, varscan2
- CDH17 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 178/596 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.194); catalogued as rs746585967; called by muse, mutect2, varscan2
- CDH22 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 25/534 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1284622908, COSV64837536; called by muse, mutect2
- CDH4 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 226/441 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.11); catalogued as rs888923510; called by muse, mutect2, varscan2
- CDHR2 | c.2746A>G p.I916V | Missense Mutation (SNP) | VAF 404/655 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as COSV56134667; called by muse, varscan2
- CDK11A | c.1148C>T p.T383M (on ENST00000378633 / NM_001313896.2; = p.T380M on NM_024011.4) | Missense Mutation (SNP) | VAF 251/586 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs538694157; called by muse, mutect2, varscan2
- CELF4 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 196/387 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV58450625; called by muse, mutect2, varscan2
- CELSR3 | c.4835G>A p.R1612Q | Missense Mutation (SNP) | VAF 197/408 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.294); catalogued as rs373621912; called by muse, mutect2, varscan2
- CEP128 | c.1637T>C p.L546S | Missense Mutation (SNP) | VAF 176/386 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs141072132; called by muse, mutect2, varscan2
- CEP170B | c.4730C>T p.P1577L (on ENST00000453495; = p.P1506L on NM_015005.3) | Missense Mutation (SNP) | VAF 280/552 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as rs769122597; called by muse, mutect2, varscan2
- CEP192 | c.5402G>A p.R1801Q | Missense Mutation (SNP) | VAF 173/419 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as rs753603607, COSV58067415; called by muse, mutect2, varscan2
- CEP192 | c.7361G>A p.G2454E | Missense Mutation (SNP) | VAF 240/590 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1359674784; called by muse, mutect2
- CEP97 | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 378/379 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs570855126; called by muse, varscan2
- CFAP157 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 207/403 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs866067906, COSV58852132; called by muse, mutect2, varscan2
- CFAP410 | c.441_444del p.E148Afs*13 | Frame Shift Del (DEL) | VAF 278/668 reads (42%) | catalogued as rs756970705; called by mutect2, pindel, varscan2
- CFAP47 | c.1511T>C p.L504S | Missense Mutation (SNP) | VAF 207/208 reads (100%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as rs1245796900; called by muse, varscan2
- CFAP65 | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 347/684 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377355595; called by muse, mutect2, varscan2
- CFC1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 178/777 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs567136194, COSV52090420; called by muse, mutect2, varscan2
- CHD3 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 248/565 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs759303159; called by muse, mutect2, varscan2
- CHEK2 | c.761T>C p.V254A (on ENST00000382580 / NM_001005735.2; = p.V211A on NM_007194.4) | Missense Mutation (SNP) | VAF 126/269 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.094); catalogued as CD160108; called by muse, mutect2, varscan2
- CHRD | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 239/459 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs750433253, COSV52607354; called by muse, mutect2, varscan2
- CHRD | c.2279C>A p.P760H | Missense Mutation (SNP) | VAF 228/518 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369623177, COSV99200765; called by muse, mutect2, varscan2
- CHRNB2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 246/486 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201393088, COSV100872615; called by muse, mutect2, varscan2
- CHSY3 | c.1192A>G p.R398G | Missense Mutation (SNP) | VAF 235/703 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV59284700; called by muse, mutect2, varscan2
- CIITA | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 283/558 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs199476070; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- CLIC6 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 415/794 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as rs1454173983; called by muse, mutect2, varscan2
- CLINT1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 458/719 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764235760, COSV99753388; called by muse, mutect2, varscan2
- CLNK | c.80del p.N27Tfs*17 | Frame Shift Del (DEL) | VAF 172/411 reads (42%) | catalogued as rs1430451531; called by mutect2, pindel, varscan2
- CLTB | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 411/630 reads (65%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.754); catalogued as rs770160355; called by muse, varscan2
- CLTRN | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs992520260; called by muse, mutect2
- CNIH3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 238/556 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs187848266, COSV99685839; called by muse, mutect2, varscan2
- CNNM1 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 187/339 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs201507104; called by muse, mutect2, varscan2
- CNR1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 260/701 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs267601156; called by muse, mutect2, varscan2
- COA4 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 345/654 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs146693705; called by muse, mutect2, varscan2
- COL19A1 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 123/428 reads (29%) | catalogued as rs759896577, COSV100506480, COSV59573575; called by muse, mutect2, varscan2
- COL21A1 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 122/457 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV55176092; called by muse, mutect2, varscan2
- COL22A1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 333/967 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401231530; called by muse, mutect2, varscan2
- COL5A3 | c.2999del p.P1000Qfs*144 | Frame Shift Del (DEL) | VAF 193/444 reads (43%) | catalogued as rs760926657; called by mutect2, pindel, varscan2
- COL6A6 | c.6125G>A p.R2042H | Missense Mutation (SNP) | VAF 238/472 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as rs368469507; called by muse, mutect2, varscan2
- COLGALT2 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 279/606 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs780516386, COSV62300903; called by muse, mutect2, varscan2
- CPEB2 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 124/259 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as rs1162407034, COSV52592867; called by muse, mutect2, varscan2
- CPED1 | c.2778del p.K926Nfs*6 | Frame Shift Del (DEL) | VAF 160/446 reads (36%) | catalogued as rs777945397; called by mutect2, pindel, varscan2
- CPNE2 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 233/509 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51963022; called by muse, mutect2, varscan2
- CPT1C | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 177/366 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); catalogued as rs149943122; called by muse, mutect2, varscan2
- CROCC2 | c.4660G>A p.G1554R | Missense Mutation (SNP) | VAF 225/501 reads (45%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.389); catalogued as rs568085134; called by muse, mutect2, varscan2
- CRTC2 | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 226/500 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747047912, COSV57841827, COSV57846253; called by muse, mutect2
- CRYBB3 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 245/535 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772868069, COSV99309045; called by muse, mutect2, varscan2
- CSAD | c.649G>T p.G217W (on ENST00000444623 / NM_001244705.2; = p.G244W on NM_015989.5) | Missense Mutation (SNP) | VAF 158/339 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99914715; called by muse, mutect2, varscan2
- CSGALNACT1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 162/555 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as rs1029503064; called by muse, mutect2, varscan2
- CSMD2 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 204/463 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200867038, COSV99585859; called by muse, mutect2, varscan2
- CSPG4 | c.1771A>G p.T591A | Missense Mutation (SNP) | VAF 274/592 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.1); catalogued as rs1408308659; called by muse, varscan2
- CSRP2 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 322/621 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60702058; called by muse, mutect2, varscan2
- CTBP1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 392/803 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs764862588, COSV52071459; called by muse, mutect2, varscan2
- CTSG | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 198/459 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV53534971; called by muse, mutect2, varscan2
- CTU1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 313/618 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV70292214; called by muse, mutect2, varscan2
- CUL7 | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 183/564 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs757730802, COSV54815917; called by muse, mutect2, varscan2
- CYP1A2 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 268/578 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV59659790; called by mutect2, varscan2
- CYP2C18 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 214/419 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs749885860; called by muse, mutect2, varscan2
- CYP4V2 | c.571del p.Y191Tfs*7 | Frame Shift Del (DEL) | VAF 136/378 reads (36%) | catalogued as rs1467050790; called by mutect2, pindel, varscan2
- CYP7B1 | c.1253T>G p.F418C | Missense Mutation (SNP) | VAF 129/372 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59590705; called by muse, mutect2, varscan2
- CYP7B1 | c.392dup p.N131Kfs*3 | Frame Shift Ins (INS) | VAF 112/370 reads (30%) | catalogued as rs748480664; called by mutect2, varscan2
- DAGLB | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 124/277 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1231346406; called by muse, mutect2, varscan2
- DAPL1 | c.127del p.T43Qfs*21 | Frame Shift Del (DEL) | VAF 139/372 reads (37%) | catalogued as rs763165810; called by mutect2, pindel, varscan2
- DBF4 | c.1223del p.K408Sfs*16 | Frame Shift Del (DEL) | VAF 52/546 reads (10%) | catalogued as rs749089320; called by mutect2, pindel
- DCAF12 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 198/428 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs779607013; called by muse, mutect2, varscan2
- DCC | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 138/284 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs748884864, COSV59113651; called by muse, mutect2, varscan2
- DCLK1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 159/344 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV55186866; called by muse, mutect2, varscan2
- DDX18 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 159/294 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs187810830; called by muse, mutect2, varscan2
- DDX43 | c.1092del p.G365Vfs*2 | Frame Shift Del (DEL) | VAF 181/563 reads (32%) | catalogued as rs1424884917, COSV64836411; called by mutect2, pindel, varscan2
- DIO3 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 363/757 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1312207192; called by muse, mutect2, varscan2
- DLC1 | c.1529C>T p.A510V (on ENST00000276297 / NM_001348081.2; = p.A73V on NM_006094.5) | Missense Mutation (SNP) | VAF 160/540 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1064795440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 284/608 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs531588076; called by muse, mutect2, varscan2
- DLGAP2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 338/902 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.401); catalogued as rs754396312, COSV70094193; called by muse, mutect2, varscan2
- DMD | c.5239G>A p.D1747N | Missense Mutation (SNP) | VAF 269/269 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV63745956; called by muse, mutect2, varscan2
- DNAH3 | c.8457C>T p.S2819= | Splice Region (SNP) | VAF 137/280 reads (49%) | catalogued as rs754426138, COSV54509182; called by muse, mutect2, varscan2
- DNAH3 | c.3287T>A p.I1096N | Missense Mutation (SNP) | VAF 229/457 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99764731; called by muse, mutect2, varscan2
- DNM2 | c.2180A>G p.H727R (on ENST00000355667 / NM_001005360.3; = p.H723R on NM_004945.3) | Missense Mutation (SNP) | VAF 257/563 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs1334633159; called by muse, mutect2, varscan2
- DOCK10 | c.4979G>A p.R1660H | Missense Mutation (SNP) | VAF 171/401 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1305763186, COSV51420167; called by muse, varscan2
- DOCK5 | c.1735del p.M579Wfs*8 | Frame Shift Del (DEL) | VAF 99/322 reads (31%) | catalogued as rs1282784562; called by mutect2, varscan2
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 108/421 reads (26%) | catalogued as rs1239294263; called by pindel, varscan2
- DOCK6 | c.1987C>T p.Q663* | Nonsense Mutation (SNP) | VAF 168/346 reads (49%) | catalogued as rs936266747; called by muse, varscan2
- DOCK6 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 180/382 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); catalogued as COSV53917121; called by muse, varscan2
- DOT1L | c.2925del p.F975Lfs*93 | Frame Shift Del (DEL) | VAF 347/862 reads (40%) | catalogued as COSV67112023; called by mutect2, pindel, varscan2
- DPEP2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 190/397 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1248948278; called by muse, mutect2, varscan2
- DPF2 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 249/500 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1467910075; called by muse, mutect2, varscan2
- DPP9 | c.2033A>G p.D678G (on ENST00000598800; = p.D707G on NM_139159.5) | Missense Mutation (SNP) | VAF 327/643 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs753225029; called by muse, mutect2, varscan2
- DPP9 | c.40G>A p.A14T (on ENST00000598800; = p.A43T on NM_139159.5) | Missense Mutation (SNP) | VAF 363/732 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs558641911, COSV53592216; called by muse, mutect2, varscan2
- DRICH1 | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 136/312 reads (44%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.801); catalogued as COSV58503113; called by muse, mutect2, varscan2
- DSCAML1 | c.5854C>T p.R1952W (on ENST00000321322; = p.R1892W on NM_020693.4) | Missense Mutation (SNP) | VAF 170/345 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs201027576, COSV58387248; called by muse, mutect2, varscan2
- DTHD1 | c.164dup p.N55Kfs*2 (on ENST00000456874; = p.N180Kfs*2 on NM_001170700.3) | Frame Shift Ins (INS) | VAF 146/312 reads (47%) | catalogued as rs34134908; called by mutect2, varscan2
- DUOX2 | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 67/490 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs750364813, COSV66534315; called by muse, mutect2, varscan2
- DYM | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 132/336 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.554); catalogued as rs1177548570, COSV53988938; called by muse, mutect2, varscan2
- DYNC2I1 | c.1550A>G p.D517G | Missense Mutation (SNP) | VAF 151/327 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV101337729; called by muse, mutect2, varscan2
- EBF3 | c.1489G>A p.A497T (on ENST00000355311 / NM_001375392.1; = p.A488T on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 276/592 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.047); catalogued as rs138447716, COSV100799028; called by muse, varscan2
- ECPAS | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 218/442 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52194898; called by muse, varscan2
- EFCAB1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 229/714 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs753689165, COSV50617909; called by muse, varscan2
- EFR3B | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 204/440 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs894458724; called by muse, mutect2, varscan2
- EGFR | c.2749G>A p.G917R | Missense Mutation (SNP) | VAF 246/548 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775695605, COSV51776216, COSV99296123; called by muse, mutect2
- EIF3G | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 179/359 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV53451288; called by muse, mutect2, varscan2
- EML6 | c.5298del p.K1766Nfs*20 | Frame Shift Del (DEL) | VAF 166/418 reads (40%) | catalogued as rs869287646; called by mutect2, pindel, varscan2
- ENAH | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 198/421 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs1261936433; called by muse, mutect2, varscan2
- EPB41L2 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 83/390 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as rs1174372686, COSV61356877; called by muse, mutect2, varscan2
- EPC1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 107/261 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433910452, COSV53923041; called by muse, mutect2, varscan2
- EPHA10 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 332/629 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as rs781544726, COSV60402475; called by muse, mutect2, varscan2
- EPHA3 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 241/497 reads (48%) | catalogued as rs1472226095, COSV60719015, COSV99069576; called by muse, mutect2, varscan2
- EPHA7 | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 203/655 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV65170401; called by muse, mutect2, varscan2
- EPPK1 | c.2177C>T p.T726M | Missense Mutation (SNP) | VAF 516/1548 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782045792; called by muse, mutect2, varscan2
- ERBIN | c.3830del p.P1277Lfs*14 (on ENST00000284037 / NM_001253697.2; = p.P1236Lfs*14 on NM_018695.4) | Frame Shift Del (DEL) | VAF 193/520 reads (37%) | catalogued as rs781559768; called by pindel, varscan2
- ESPN | c.3241C>T p.R1081C | Missense Mutation (SNP) | VAF 272/570 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs1449515084; called by muse, varscan2
- ETNK2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 284/598 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1420802320, COSV99689654; called by muse, mutect2, varscan2
- EVPL | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 197/410 reads (48%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs1309525993; called by muse, varscan2
- EYA1 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 157/564 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs727503047, COSV58175577; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYA4 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 195/703 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1044216762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EZHIP | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 441/454 reads (97%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1006910285, COSV57955307; called by muse, mutect2, varscan2
- FAM120A | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 202/444 reads (45%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.552); catalogued as rs765247935; called by muse, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 140/404 reads (35%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM13C | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 277/546 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1304753095, COSV53245191; called by muse, mutect2, varscan2
- FAM171A2 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 237/515 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs548562099; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 334/830 reads (40%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM47C | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 361/363 reads (99%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.687); catalogued as rs1556332293, COSV100792488; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 120/124 reads (97%) | catalogued as rs748967872; called by mutect2, varscan2
- FAT2 | c.12902G>A p.R4301H | Missense Mutation (SNP) | VAF 273/894 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147369556; called by muse, mutect2, varscan2
- FAT2 | c.10383dup p.Y3462Lfs*26 | Frame Shift Ins (INS) | VAF 183/646 reads (28%) | catalogued as rs747011618; called by mutect2, varscan2
- FBLIM1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 410/801 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748856645, COSV60028625; called by muse, mutect2, varscan2
- FBLN2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 324/620 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs371872562; called by muse, mutect2, varscan2
- FBRSL1 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 397/757 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs1233605862; called by muse, varscan2
- FBXO15 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 161/338 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs202075662, COSV99077190; called by muse, varscan2
- FBXO33 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 175/349 reads (50%) | catalogued as COSV53233777; called by muse, mutect2, varscan2
- FBXO38 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 196/603 reads (33%) | catalogued as rs753065225; called by muse, mutect2, varscan2
- FGD6 | c.2692C>T p.R898W | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1269009624, COSV59696433; called by muse, mutect2, varscan2
- FLG | c.7159G>A p.G2387R | Missense Mutation (SNP) | VAF 223/539 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs775764952, COSV100911672; called by muse, mutect2, varscan2
- FMO4 | c.1558del p.A520Hfs*18 | Frame Shift Del (DEL) | VAF 244/649 reads (38%) | catalogued as rs770011693, COSV100882071; called by mutect2, pindel, varscan2
- FNDC1 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 396/1125 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); catalogued as rs771247742, COSV51935468; called by muse, mutect2, varscan2
- FOXF1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 343/705 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52286748; called by muse, mutect2, varscan2
- FOXK1 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 289/620 reads (47%) | catalogued as rs1397177767, COSV61065914; called by muse, varscan2
- FRMD6 | c.1099C>T p.R367W (on ENST00000344768 / NM_001267046.2; = p.R359W on NM_152330.4) | Missense Mutation (SNP) | VAF 235/476 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as rs35856363, COSV100655572; called by muse, mutect2, varscan2
- FUT4 | c.1158C>G p.F386L | Missense Mutation (SNP) | VAF 315/635 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62469505; called by muse, mutect2, varscan2
- FUT8 | c.1417C>T p.R473* (on ENST00000360689 / NM_001371534.1; = p.R310* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 122/241 reads (51%) | catalogued as COSV61281308; called by muse, mutect2, varscan2
- FXR1 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 190/365 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as COSV59766678; called by muse, mutect2, varscan2
- GABRB1 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 322/622 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV54986839, COSV54988273, COSV55000495; called by muse, mutect2, varscan2
- GABRP | c.775T>G p.L259V | Missense Mutation (SNP) | VAF 236/746 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs747925903; called by mutect2, varscan2
- GAREM1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 232/472 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422190759, COSV52505694; called by muse, mutect2, varscan2
- GCAT | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 218/457 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142242726; called by muse, mutect2, varscan2
- GFY | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 219/497 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1429686267; called by muse, mutect2, varscan2
- GGT7 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 332/634 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as rs34687214; called by muse, mutect2, varscan2
- GIMAP5 | c.890del p.F297Sfs*30 | Frame Shift Del (DEL) | VAF 170/364 reads (47%) | catalogued as rs774162620, COSV57529761, COSV57529909; called by mutect2, varscan2
- GLI3 | c.3173G>A p.R1058Q | Missense Mutation (SNP) | VAF 271/538 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs760174184, COSV67885478, COSV67885819; called by muse, mutect2, varscan2
- GNAI2 | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 300/651 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553703488; called by muse, mutect2, varscan2
- GNAS | c.1750G>T p.G584W | Missense Mutation (SNP) | VAF 305/674 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as COSV100005342; called by muse, mutect2, varscan2
- GNAS | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 209/430 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as CM152407; called by muse, mutect2, varscan2
- GNB1L | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 307/656 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61548607; called by muse, mutect2, varscan2
- GPC5 | c.1281T>G p.S427R | Missense Mutation (SNP) | VAF 131/274 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.267); catalogued as COSV65578710; called by muse, mutect2, varscan2
- GPM6A | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 178/385 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.224); catalogued as COSV99703150; called by muse, mutect2, varscan2
- GPR137 | c.1091del p.P364Lfs*? | Frame Shift Del (DEL) | VAF 230/476 reads (48%) | catalogued as COSV100464157, COSV57402216; called by mutect2, varscan2
- GPR155 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 198/447 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs1559113891; called by muse, mutect2, varscan2
- GPR155 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 183/379 reads (48%) | catalogued as rs375197307; called by muse, mutect2, varscan2
- GPR25 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 297/617 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.095); catalogued as rs752404907; called by muse, mutect2, varscan2
- GPR68 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 248/512 reads (48%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.864); catalogued as rs1448146948, COSV53176500; called by muse, mutect2, varscan2
- GPRIN1 | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 305/841 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1404322981; called by muse, mutect2, varscan2
- GRIA1 | c.2704G>T p.G902* | Nonsense Mutation (SNP) | VAF 236/357 reads (66%) | catalogued as COSV53630561; called by muse, varscan2
- GRIN2B | c.3505G>A p.G1169R | Missense Mutation (SNP) | VAF 251/598 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.754); catalogued as rs777639067, COSV101663161, COSV74207066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM1 | c.3131C>T p.A1044V | Missense Mutation (SNP) | VAF 300/957 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV51291708; called by muse, mutect2, varscan2
- GRM4 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 239/799 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1338131065, COSV65212346; called by muse, mutect2, varscan2
- GRN | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 227/498 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs757831826, COSV50007966, COSV50008726; called by muse, mutect2, varscan2
- GTDC1 | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 167/329 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763722216; called by muse, mutect2, varscan2
- GYS2 | c.1820A>G p.H607R | Missense Mutation (SNP) | VAF 171/354 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.348); catalogued as rs886049155; ClinVar: uncertain significance; called by muse, varscan2
- H4C12 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 123/521 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs1314153326; called by muse, mutect2, varscan2
- HACE1 | c.1793del p.R598Lfs*11 | Frame Shift Del (DEL) | VAF 136/488 reads (28%) | catalogued as COSV53499381; called by mutect2, pindel, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 136/304 reads (45%) | catalogued as rs748396956; called by mutect2, varscan2
- HBM | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 394/785 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs774748950; called by muse, mutect2, varscan2
- HCFC2 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 134/279 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); catalogued as COSV99983114; called by muse, mutect2, varscan2
- HDAC5 | c.695del p.P232Lfs*32 | Frame Shift Del (DEL) | VAF 222/516 reads (43%) | catalogued as COSV56820100; called by mutect2, pindel, varscan2
- HDDC3 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 228/520 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs868073323; called by muse, varscan2
- HEATR6 | c.1311del p.V438Ffs*24 | Frame Shift Del (DEL) | VAF 186/422 reads (44%) | catalogued as rs748699945, COSV51743560; called by mutect2, varscan2
- HECTD4 | c.10351G>A p.G3451R | Missense Mutation (SNP) | VAF 18/564 reads (3%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.251); catalogued as rs1454591120, COSV101106980; called by muse, mutect2
- HECTD4 | c.4645C>T p.R1549C | Missense Mutation (SNP) | VAF 209/426 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs776696918, COSV101106554; called by muse, mutect2, varscan2
- HEPACAM | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 187/378 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs549252759, COSV53430756, COSV53432474; called by muse, mutect2, varscan2
- HERC1 | c.3452G>A p.R1151Q | Missense Mutation (SNP) | VAF 226/488 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs371163845; called by muse, mutect2, varscan2
- HERC2 | c.11684G>A p.R3895H | Missense Mutation (SNP) | VAF 194/388 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.13); catalogued as rs945751718; called by muse, mutect2, varscan2
- HERC2 | c.2984C>T p.T995M | Missense Mutation (SNP) | VAF 273/633 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.416); catalogued as rs147116947; called by muse, mutect2, varscan2
- HIF3A | c.1880G>A p.S627N (on ENST00000377670 / NM_152795.4; = p.S558N on NM_022462.4) | Missense Mutation (SNP) | VAF 238/479 reads (50%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.012); catalogued as COSV99355912; called by muse, varscan2
- HIPK2 | c.3022T>C p.S1008P | Missense Mutation (SNP) | VAF 256/525 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs752980431; called by muse, mutect2, varscan2
- HIVEP2 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 193/621 reads (31%) | catalogued as COSV50007394; called by muse, mutect2, varscan2
- HIVEP2 | c.1498A>G p.S500G | Missense Mutation (SNP) | VAF 253/787 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1424214061; called by muse, mutect2, varscan2
- HK1 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 310/627 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1332719473; called by muse, mutect2
- HMGCS2 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 260/531 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767236647, COSV65567358; called by muse, mutect2, varscan2
- HNRNPL | c.1002del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 210/520 reads (40%) | catalogued as COSV99670288; called by mutect2, pindel, varscan2
- HOXC10 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 256/546 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.035); catalogued as rs878883787, COSV57727010; called by muse, varscan2
- HOXD12 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 187/381 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as rs779274101, COSV66832344; called by muse, mutect2, varscan2
- HRNR | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 321/641 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs765957331, COSV100913936; called by muse, mutect2, varscan2
- HS1BP3 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 281/594 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs760156212, COSV58311926; called by muse, mutect2, varscan2
- HS6ST3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 235/461 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.251); catalogued as rs1268310394, COSV65009296; called by muse, mutect2, varscan2
- HSPA12B | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 276/593 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as rs1267552512, COSV53924280; called by muse, mutect2, varscan2
- HTR1A | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 175/374 reads (47%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1427602417; called by muse, mutect2, varscan2
- HTR5A | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 215/425 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs780790670, COSV55282302, COSV55284114; called by muse, mutect2, varscan2
- HUS1B | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 117/402 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as COSV57871685; called by muse, mutect2, varscan2
- HUWE1 | c.7561C>T p.R2521C | Missense Mutation (SNP) | VAF 276/276 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1221267143, COSV53335206; called by muse, varscan2
- IDE | c.1168A>G p.I390V | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs764826071; called by muse, varscan2
- IFT122 | c.896del p.G299Vfs*71 (on ENST00000348417 / NM_052989.3; = p.G240Vfs*71 on NM_018262.4) | Frame Shift Del (DEL) | VAF 260/616 reads (42%) | catalogued as rs778534085; called by mutect2, pindel, varscan2
- IGDCC3 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 237/537 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1209689800; called by muse, mutect2, varscan2
- IL1R2 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 234/527 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs145651311, COSV100208321; called by muse, mutect2, varscan2
- IL1RL1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 115/250 reads (46%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.701); catalogued as COSV52115064; called by muse, mutect2, varscan2
- INCENP | c.1433C>A p.T478N | Missense Mutation (SNP) | VAF 209/444 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV53921519; called by muse, mutect2, varscan2
- INF2 | c.1864del p.R622Gfs*18 | Frame Shift Del (DEL) | VAF 240/616 reads (39%) | catalogued as rs1459726028; called by mutect2, pindel, varscan2
- INPP5J | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 79/760 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV58512900; called by muse, mutect2, varscan2
- INPPL1 | c.164C>G p.A55G | Missense Mutation (SNP) | VAF 229/501 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs1565381470; called by muse, mutect2, varscan2
- INPPL1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 220/442 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs200057735; called by muse, varscan2
- INPPL1 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 232/474 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293622519, COSV53354767, COSV53358764, COSV99996721; called by muse, mutect2, varscan2
- INTS6L | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 133/134 reads (99%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs143980255, COSV66085332; called by muse, mutect2, varscan2
- IRF2BP1 | c.367del p.L123Cfs*39 | Frame Shift Del (DEL) | VAF 291/802 reads (36%) | catalogued as COSV56195278; called by pindel, varscan2
- IRS2 | c.3265G>C p.A1089P | Missense Mutation (SNP) | VAF 310/681 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs780127725, COSV65477933; called by mutect2, varscan2
- IRX2 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 340/706 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.044); catalogued as rs1260443534, COSV57414036; called by muse, mutect2, varscan2
- ITGAE | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 239/469 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1245613648; called by muse, mutect2, varscan2
- ITGB8 | c.*5del | Frame Shift Del (DEL) | VAF 107/248 reads (43%) | catalogued as rs770665724; called by mutect2, pindel, varscan2
- ITK | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 157/600 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70060494; called by muse, mutect2, varscan2
- JAG2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 288/622 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389623306; called by muse, varscan2
- JAM3 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 178/382 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs762709121, COSV54451756; called by muse, mutect2, varscan2
- JAM3 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 197/454 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs367727226; called by muse, mutect2, varscan2
- KATNIP | c.4843C>T p.R1615* | Nonsense Mutation (SNP) | VAF 244/515 reads (47%) | catalogued as rs150515359; called by muse, mutect2, varscan2
- KCNB2 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 334/993 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs781046739, COSV73049383; called by muse, mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 257/551 reads (47%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNG4 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 334/675 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.792); catalogued as rs371214019; called by muse, mutect2, varscan2
- KCNK5 | c.1138G>C p.A380P | Missense Mutation (SNP) | VAF 310/935 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV63989083; called by muse, mutect2, varscan2
- KCNMA1 | c.3584C>T p.S1195L (on ENST00000286628 / NM_001161352.2; = p.S1137L on NM_002247.4) | Missense Mutation (SNP) | VAF 193/418 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs202024249, COSV54296032; called by muse, mutect2, varscan2
- KCNS2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 279/919 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1480950741, COSV99750882; called by muse, mutect2, varscan2
- KDM3A | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 234/498 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs754148984, COSV57225727; called by muse, mutect2, varscan2
- KDM4B | c.2638G>A p.V880M | Missense Mutation (SNP) | VAF 302/595 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1268282336; called by muse, varscan2
- KDM6A | c.3331C>T p.R1111C | Missense Mutation (SNP) | VAF 244/244 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs763592177, COSV65038074, COSV65038305, COSV65040911, COSV65042699; called by muse, mutect2, varscan2
- KDM6A | c.3502G>T p.V1168F | Missense Mutation (SNP) | VAF 149/149 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV65045879; called by muse, mutect2, varscan2
- KIAA1549L | c.949G>A p.A317T (on ENST00000321505; = p.A614T on NM_012194.3) | Missense Mutation (SNP) | VAF 242/507 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1217319745; called by muse, mutect2, varscan2
- KIAA1549L | c.4869G>A p.P1623= (on ENST00000321505; = p.P1920= on NM_012194.3) | Splice Region (SNP) | VAF 134/275 reads (49%) | catalogued as rs771446533, COSV58586351; called by muse, mutect2, varscan2
- KIF15 | c.1354T>A p.F452I | Missense Mutation (SNP) | VAF 103/247 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.779); catalogued as rs936284136; called by muse, mutect2, varscan2
- KIF18B | c.1178dup p.G394Rfs*32 (on ENST00000593135 / NM_001265577.2; = p.G394Rfs*44 on NM_001264573.2) | Frame Shift Ins (INS) | VAF 198/535 reads (37%) | catalogued as rs1347932473; called by mutect2, pindel, varscan2
- KIF1A | c.4790C>T p.T1597M (on ENST00000320389 / NM_001379639.1; = p.T1589M on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 256/546 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1468911667; called by muse, mutect2, varscan2
- KIF6 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 110/418 reads (26%) | catalogued as rs777890702; called by mutect2, pindel, varscan2
- KIFC2 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 237/813 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs184801242; called by muse, mutect2, varscan2
- KIRREL2 | c.2070del p.F691Sfs*40 | Frame Shift Del (DEL) | VAF 358/815 reads (44%) | catalogued as COSV99383816; called by mutect2, pindel, varscan2
- KLF14 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 320/642 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1554470843; called by muse, varscan2
- KLF15 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 236/535 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.333); catalogued as rs753392896, COSV99955064; called by muse, varscan2
- KLHDC7B | c.488del p.G163Afs*83 (on ENST00000395676; = p.G804Afs*83 on NM_138433.5) | Frame Shift Del (DEL) | VAF 327/764 reads (43%) | catalogued as rs1435543889; called by mutect2, pindel, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 118/230 reads (51%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2A | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 200/429 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs1555035714, COSV63288980, COSV63291142; called by muse, mutect2, varscan2
- KMT2A | c.10161G>T p.Q3387H | Missense Mutation (SNP) | VAF 255/471 reads (54%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1462963975; called by muse, mutect2, varscan2
- KMT2C | c.14530G>A p.A4844T | Missense Mutation (SNP) | VAF 193/411 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469176725, COSV51277101; called by muse, mutect2, varscan2
- KMT2C | c.6865C>T p.R2289C | Missense Mutation (SNP) | VAF 204/443 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs764025360; called by muse, varscan2
- KMT2D | c.8341C>G p.P2781A | Missense Mutation (SNP) | VAF 268/571 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1434600307, COSV104396936, COSV56451437; called by muse, mutect2, varscan2
- KNDC1 | c.4094G>T p.G1365V | Missense Mutation (SNP) | VAF 267/552 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as COSV58841041; called by muse, mutect2, varscan2
- KNL1 | c.3728T>C p.L1243P (on ENST00000346991 / NM_170589.5; = p.L1217P on NM_144508.5) | Missense Mutation (SNP) | VAF 217/399 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.693); catalogued as rs758895510; called by muse, mutect2, varscan2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 114/196 reads (58%) | catalogued as rs761148574; called by mutect2, varscan2
- KRT81 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 32/596 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as rs1257054348; called by muse, mutect2
- KRTAP19-5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 187/339 reads (55%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as rs112006874, COSV61858873; called by muse, mutect2, varscan2
- KRTAP4-9 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 242/588 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as rs1231970295; called by muse, varscan2
- KSR2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 320/612 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs548971268, COSV100351462, COSV60366465, COSV60384960; called by muse, mutect2, varscan2
- LAMA4 | c.4246G>T p.G1416* (on ENST00000230538 / NM_001105206.3; = p.G1409* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 151/484 reads (31%) | catalogued as COSV57895500; called by muse, mutect2, varscan2
- LAMA5 | c.5800C>T p.R1934C | Missense Mutation (SNP) | VAF 285/569 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs750315166; called by muse, mutect2, varscan2
- LAMA5 | c.3740C>T p.P1247L | Missense Mutation (SNP) | VAF 33/787 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.15); catalogued as rs1273670913; called by muse, mutect2
- LGALS3BP | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 276/554 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs377712591; called by muse, mutect2, varscan2
- LHX9 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 222/516 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs768603459; called by muse, mutect2, varscan2
- LILRA2 | c.1355G>A p.R452H (on ENST00000391738 / NM_001130917.3; = p.R435H on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 342/713 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs199988092, COSV52191718; called by muse, mutect2, varscan2
- LIN37 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 68/750 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.922); catalogued as rs368622689; called by muse, mutect2
- LMF2 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 319/674 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141701845; called by muse, mutect2, varscan2
- LMNA | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 273/582 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV61541879; called by muse, mutect2, varscan2
- LMNTD2 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 298/670 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752614516; called by muse, mutect2, varscan2
- LMOD3 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 176/367 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs376653017, COSV70456400; called by muse, mutect2, varscan2
- LPA | c.3120del p.F1040Lfs*5 | Frame Shift Del (DEL) | VAF 112/408 reads (27%) | catalogued as rs753812356; called by mutect2, pindel, varscan2
- LRFN2 | c.2212G>A p.V738M | Missense Mutation (SNP) | VAF 296/938 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs150683269; called by muse, mutect2, varscan2
- LRIT2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 274/549 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1445101374, COSV64518298; called by muse, mutect2, varscan2
- LRP12 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 160/524 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs371335155; called by muse, mutect2, varscan2
- LRP1B | c.12673G>T p.G4225* | Nonsense Mutation (SNP) | VAF 144/305 reads (47%) | catalogued as COSV67195038; called by muse, mutect2, varscan2
- LRP5 | c.3514C>T p.R1172C | Missense Mutation (SNP) | VAF 269/561 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs1394958801; called by muse, mutect2, varscan2
- LRRC19 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 95/230 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs199558016; called by muse, mutect2, varscan2
- LRRC29 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 270/609 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1438669806, COSV99050805; called by muse, varscan2
- LRRC9 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 189/398 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1175476030, COSV99580562; called by muse, mutect2, varscan2
- LRRCC1 | c.911T>A p.I304N | Missense Mutation (SNP) | VAF 116/320 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1259727719; called by muse, mutect2, varscan2
- LRRIQ1 | c.4624del p.I1542Ffs*17 | Frame Shift Del (DEL) | VAF 72/168 reads (43%) | catalogued as rs745692987; called by mutect2, varscan2
- LTBP4 | c.4201C>A p.L1401M (on ENST00000308370 / NM_001042544.1; = p.L1364M on NM_003573.2) | Missense Mutation (SNP) | VAF 261/543 reads (48%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.985); catalogued as rs1052471685; called by muse, mutect2, varscan2
- LYSMD2 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 240/479 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769063670; called by muse, mutect2, varscan2
- LZTS1 | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 262/883 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as rs768951518; called by muse, mutect2, varscan2
- MACF1 | c.14686del p.T4896Lfs*29 (on ENST00000372915; = p.T2829Lfs*29 on NM_012090.5) | Frame Shift Del (DEL) | VAF 204/501 reads (41%) | catalogued as rs775539898; called by mutect2, pindel, varscan2
- MAG | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 245/503 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs1032956121, COSV62698909; called by muse, mutect2, varscan2
- MAN2A1 | c.1916del p.N639Ifs*2 | Frame Shift Del (DEL) | VAF 123/271 reads (45%) | catalogued as rs758700583; called by mutect2, pindel, varscan2
- MAP3K21 | c.2201C>A p.A734D | Missense Mutation (SNP) | VAF 193/368 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64041723; called by muse, mutect2, varscan2
- MAP4K5 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 269/543 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV99184799; called by muse, mutect2, varscan2
- MAP7D1 | c.1252_1254del p.K418del | In Frame Del (DEL) | VAF 158/360 reads (44%) | catalogued as rs752518838; called by pindel, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 53/131 reads (40%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MAPK1IP1L | c.595T>C p.W199R | Missense Mutation (SNP) | VAF 311/613 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as rs763634125; called by muse, mutect2, varscan2
- MAPKBP1 | c.3037C>T p.H1013Y (on ENST00000456763 / NM_001128608.2; = p.H1007Y on NM_014994.3) | Missense Mutation (SNP) | VAF 140/307 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1244670976; called by muse, mutect2, varscan2
- MARS1 | c.1331T>C p.V444A | Missense Mutation (SNP) | VAF 249/497 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs780028144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARVELD3 | c.948dup p.Y317Vfs*22 | Frame Shift Ins (INS) | VAF 196/432 reads (45%) | catalogued as rs747980715; called by mutect2, varscan2
- MCHR1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 328/733 reads (45%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as rs771256039; called by muse, mutect2, varscan2
- MCMBP | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 208/485 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs755914490; called by muse, mutect2, varscan2
- MEAK7 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 197/430 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs370281146; called by muse, mutect2, varscan2
- MED15 | c.2261G>A p.R754H (on ENST00000263205 / NM_001003891.3; = p.R714H on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 288/588 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as rs368856165; called by muse, mutect2, varscan2
- MED23 | c.3163G>A p.A1055T | Missense Mutation (SNP) | VAF 268/742 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1562373867; called by muse, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 72/696 reads (10%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MEGF6 | c.4318del p.A1440Hfs*78 | Frame Shift Del (DEL) | VAF 318/765 reads (42%) | catalogued as rs759225724, COSV53895347; called by mutect2, pindel, varscan2
- MIB2 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 274/573 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs755453798; called by muse, varscan2
- MICU3 | c.803del p.N268Mfs*47 | Frame Shift Del (DEL) | VAF 84/264 reads (32%) | catalogued as rs199759760; called by mutect2, varscan2
- MID1 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 334/334 reads (100%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1169366982, COSV58198773; called by muse, varscan2
- MINAR1 | c.956C>G p.P319R | Missense Mutation (SNP) | VAF 263/520 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV59583363, COSV59584062; called by muse, mutect2, varscan2
- MMP17 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 205/443 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV62180542; called by muse, mutect2, varscan2
- MMS22L | c.3011G>A p.G1004D | Missense Mutation (SNP) | VAF 115/361 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452614379, COSV104390048, COSV51524201; called by muse, mutect2, varscan2
- MOGS | c.2293G>T p.A765S | Missense Mutation (SNP) | VAF 273/580 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1482002989; called by muse, mutect2, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 76/181 reads (42%) | catalogued as rs757379917; called by mutect2, varscan2
- MPP2 | c.487C>T p.R163C (on ENST00000461854 / NM_001278372.2; = p.R139C on NM_005374.5) | Missense Mutation (SNP) | VAF 234/455 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757493946, COSV99290631; called by muse, mutect2, varscan2
- MRC2 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 242/495 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57640753, COSV57641679; called by muse, mutect2, varscan2
- MROH1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 240/756 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765665232, COSV58192057; called by muse, mutect2, varscan2
- MRPL53 | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 219/466 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs968380682; called by muse, mutect2, varscan2
- MS4A1 | c.708del p.E237Nfs*6 | Frame Shift Del (DEL) | VAF 86/182 reads (47%) | catalogued as rs779922206; called by mutect2, varscan2
- MS4A6A | c.562_563dup p.M189* | Frame Shift Ins (INS) | VAF 82/218 reads (38%) | catalogued as rs1565096834; called by mutect2, varscan2
- MSANTD1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 243/548 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1474075287, COSV101433714; called by muse, mutect2, varscan2
- MSI1 | c.345del p.L116Cfs*3 | Frame Shift Del (DEL) | VAF 290/771 reads (38%) | catalogued as rs748469666; called by mutect2, pindel, varscan2
- MTA3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 131/262 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as rs768192257; called by muse, mutect2, varscan2
- MTMR1 | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs373536793; called by muse, mutect2
- MUC16 | c.36080G>A p.R12027Q | Missense Mutation (SNP) | VAF 204/407 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as rs769222839, COSV67471709; called by muse, mutect2, varscan2
- MUC16 | c.6263C>T p.T2088I | Missense Mutation (SNP) | VAF 276/551 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV101199974; called by muse, mutect2, varscan2
- MUC6 | c.7111C>T p.R2371C | Missense Mutation (SNP) | VAF 322/712 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1186646568, COSV59963310, COSV59963815; called by muse, mutect2, varscan2
- MYCBP2 | c.3850C>T p.P1284S (on ENST00000357337; = p.P1322S on NM_015057.5) | Missense Mutation (SNP) | VAF 188/409 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62017074; called by muse, mutect2, varscan2
- MYH7B | c.4510C>T p.R1504W | Missense Mutation (SNP) | VAF 273/553 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771512439, COSV52685284; called by muse, mutect2, varscan2
- MYH9 | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 271/589 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs376240562; called by muse, mutect2, varscan2
- MYO18B | c.3303G>A p.W1101* | Nonsense Mutation (SNP) | VAF 30/535 reads (6%) | catalogued as rs1178875928; called by muse, mutect2
- MYO1F | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 183/403 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as CM090126; called by muse, mutect2, varscan2
- MYOM2 | c.107del p.K36Sfs*13 | Frame Shift Del (DEL) | VAF 153/605 reads (25%) | catalogued as rs1360158578; called by mutect2, pindel, varscan2
- MYT1L | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 296/687 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.109); catalogued as COSV67713140; called by muse, mutect2, varscan2
- NAALADL2 | c.1554del p.N520Mfs*12 | Frame Shift Del (DEL) | VAF 114/262 reads (44%) | catalogued as rs1478908176, COSV69154859; called by mutect2, pindel, varscan2
- NAGLU | c.2021G>T p.R674L | Missense Mutation (SNP) | VAF 252/513 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104894590, CM950832, COSV56795017; called by muse, mutect2, varscan2
- NAV2 | c.2458G>A p.A820T (on ENST00000396087 / NM_001244963.2; = p.A797T on NM_145117.5) | Missense Mutation (SNP) | VAF 297/576 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs140354139, COSV62320806; called by muse, mutect2, varscan2
- NBEA | c.3677C>T p.A1226V | Missense Mutation (SNP) | VAF 189/385 reads (49%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.028); catalogued as rs1348731685, COSV59779612; called by muse, mutect2, varscan2
- NCOR2 | c.4990C>A p.L1664M | Missense Mutation (SNP) | VAF 331/666 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV62292639; called by muse, mutect2, varscan2
- NDC1 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 150/302 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs1207224755, COSV52334729; called by muse, mutect2, varscan2
- NDN | c.94del p.V32Ffs*15 | Frame Shift Del (DEL) | VAF 224/564 reads (40%) | catalogued as rs1430155453; called by pindel, varscan2
- NDUFA10 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 132/313 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201798886; called by muse, mutect2, varscan2
- NEB | c.19081C>T p.R6361C | Missense Mutation (SNP) | VAF 149/334 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs542275170; called by muse, mutect2, varscan2
- NEFM | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 246/744 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55335400; called by muse, mutect2, varscan2
- NEUROD1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 284/532 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV54549697; called by muse, mutect2, varscan2
- NHLRC1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 332/953 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs368134036, COSV61481237; called by muse, mutect2, varscan2
- NID2 | c.1127del p.G376Afs*4 | Frame Shift Del (DEL) | VAF 190/502 reads (38%) | catalogued as COSV53499595; called by mutect2, pindel, varscan2
- NKX6-1 | c.237del p.L80Sfs*23 | Frame Shift Del (DEL) | VAF 311/748 reads (42%) | catalogued as rs745904099; called by mutect2, pindel, varscan2
- NLRP14 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 216/432 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100205232; called by muse, varscan2
- NLRP14 | c.2900A>G p.N967S | Missense Mutation (SNP) | VAF 222/467 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1472653484; called by muse, mutect2, varscan2
- NLRP2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 332/621 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1165462336, COSV54756823; called by muse, mutect2, varscan2
- NMBR | c.768del p.K256Nfs*45 | Frame Shift Del (DEL) | VAF 72/245 reads (29%) | catalogued as rs1470345555; called by mutect2, pindel, varscan2
- NMUR1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 315/646 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs777720090, COSV59404186; called by muse, mutect2, varscan2
- NOD1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 252/500 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565502191; called by muse, varscan2
- NOL7 | c.714dup p.Q239Tfs*7 | Frame Shift Ins (INS) | VAF 75/256 reads (29%) | catalogued as rs544905440; called by mutect2, varscan2
- NOTCH1 | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 393/762 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53043280, COSV53047338; called by muse, mutect2, varscan2
- NOVA2 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 88/166 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1423442653; called by muse, varscan2
- NPNT | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 116/249 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV59753137; called by muse, varscan2
- NPR2 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 160/322 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs1481073248; called by muse, mutect2, varscan2
- NSD1 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 281/546 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.549); catalogued as rs1215568879, COSV61775264; called by muse, mutect2, varscan2
- NSUN5 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 288/620 reads (46%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as COSV53090867; called by muse, mutect2, varscan2
- NTNG1 | c.1429G>A p.G477R (on ENST00000370068 / NM_001113226.3; = p.G376R on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 215/437 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100903292; called by muse, mutect2, varscan2
- NUDCD3 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 241/504 reads (48%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs953619201; called by muse, mutect2, varscan2
- NUP214 | c.6017C>T p.S2006L | Missense Mutation (SNP) | VAF 279/521 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763033567; called by muse, mutect2, varscan2
- NUP98 | c.5111G>A p.R1704H (on ENST00000359171 / NM_001365126.1; = p.R1687H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 159/301 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs146194229, COSV100261384; called by muse, mutect2, varscan2
- NXF1 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 262/522 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs770860085; called by muse, mutect2, varscan2
- OBSL1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 43/506 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54724951; called by muse, mutect2
- OLFM2 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 368/685 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs765662180, COSV53428450; called by muse, mutect2, varscan2
- OR10K2 | c.788A>T p.Q263L | Missense Mutation (SNP) | VAF 172/359 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV59222905; called by muse, mutect2, varscan2
- OR10W1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 209/451 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs910818427, COSV67720197; called by muse, mutect2, varscan2
- OR13D1 | c.526A>C p.M176L | Missense Mutation (SNP) | VAF 197/406 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as rs891572864; called by muse, mutect2, varscan2
- OR2T34 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 13/577 reads (2%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV100170587; called by muse, mutect2
- OR4A15 | c.445G>T p.G149* | Nonsense Mutation (SNP) | VAF 257/532 reads (48%) | catalogued as COSV59036704; called by muse, mutect2, varscan2
- OR4K14 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 183/386 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV59293272; called by muse, mutect2, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 164/506 reads (32%) | catalogued as rs1566497842; called by mutect2, varscan2
- OR4Q3 | c.833A>C p.K278T | Missense Mutation (SNP) | VAF 224/634 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59179726; called by muse, mutect2, varscan2
- OR52E6 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 206/400 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.277); catalogued as rs1306204603; called by muse, mutect2, varscan2
- OR5H1 | c.921dup p.H308Tfs*3 | Frame Shift Ins (INS) | VAF 44/152 reads (29%) | catalogued as rs750155763; called by mutect2, varscan2
- OR9H1P | c.537del p.P181Hfs*12 | Frame Shift Del (DEL) | VAF 196/448 reads (44%) | catalogued as rs950040005; called by mutect2, pindel, varscan2
- OSBP2 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 182/373 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as rs1478252504; called by muse, mutect2, varscan2
- OTX2 | c.106del p.R36Gfs*15 (on ENST00000408990 / NM_172337.3; = p.R44Gfs*15 on NM_021728.4) | Frame Shift Del (DEL) | VAF 232/555 reads (42%) | catalogued as CD124838, COSV100258088; called by mutect2, pindel, varscan2
- P3H2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 216/398 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs748750473, COSV60017755, COSV60023143; called by muse, mutect2, varscan2
- PAQR4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 365/740 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs748058094, COSV51893053; called by muse, varscan2
- PARP4 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 251/499 reads (50%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as rs758277432, COSV67964417; called by muse, mutect2, varscan2
- PCARE | c.2966del p.P989Lfs*46 | Frame Shift Del (DEL) | VAF 261/487 reads (54%) | catalogued as rs770881706; called by mutect2, varscan2
- PCDHA1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 169/360 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.052); catalogued as rs1446677911, COSV65374909; called by muse, mutect2, varscan2
- PCDHA1 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 70/509 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.436); catalogued as COSV65373700; called by muse, mutect2, varscan2
- PCDHA10 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 182/393 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.161); catalogued as COSV56481603; called by muse, mutect2, varscan2
- PCDHA7 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 365/802 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782561322, COSV65341561, COSV65345338; called by muse, mutect2, varscan2
- PCDHB11 | c.190del p.A64Lfs*16 | Frame Shift Del (DEL) | VAF 208/516 reads (40%) | catalogued as rs782500133; called by mutect2, pindel, varscan2
- PCDHB16 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 256/658 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs1371346092, COSV53357605; called by muse, mutect2
- PCDHB3 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 177/355 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50571022; called by muse, mutect2, varscan2
- PCDHB5 | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 227/459 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.242); catalogued as COSV50647253; called by muse, mutect2, varscan2
- PCDHGA6 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 390/868 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1436738898; called by muse, mutect2, varscan2
- PCDHGB3 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 226/492 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs903944197, COSV53935008; called by muse, mutect2, varscan2
- PCNX1 | c.3604del p.C1202Vfs*4 | Frame Shift Del (DEL) | VAF 137/368 reads (37%) | catalogued as COSV99456874; called by mutect2, pindel, varscan2
- PCSK5 | c.3068G>A p.G1023E | Missense Mutation (SNP) | VAF 167/334 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs748907371; called by muse, mutect2, varscan2
- PDCD10 | c.211del p.S71Afs*18 | Frame Shift Del (DEL) | VAF 140/323 reads (43%) | catalogued as CD143177; called by mutect2, pindel, varscan2
- PDE6C | c.2353A>G p.T785A | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.669); catalogued as COSV65116630; called by muse, varscan2
- PDPN | c.41C>T p.A14V (on ENST00000621990; = p.A90V on NM_006474.4) | Missense Mutation (SNP) | VAF 312/603 reads (52%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.678); catalogued as COSV53848837; called by muse, mutect2, varscan2
- PDZRN4 | c.1687C>T p.R563* (on ENST00000402685 / NM_001164595.2; = p.R305* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 184/426 reads (43%) | catalogued as rs150680549, COSV54203393; called by muse, mutect2, varscan2
- PEAR1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 371/750 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs767863459; called by muse, mutect2, varscan2
- PEDS1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 216/417 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59014001; called by muse, mutect2, varscan2
- PEX5L | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 28/636 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55858102; called by muse, mutect2
- PGC | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 188/694 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs143935750; called by muse, mutect2, varscan2
- PHF20L1 | c.1721dup p.K575Efs*5 | Frame Shift Ins (INS) | VAF 65/260 reads (25%) | catalogued as rs772333737; called by mutect2, varscan2
- PHF21B | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 250/515 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs370081683; called by muse, mutect2, varscan2
- PHGR1 | c.175dup p.H59Pfs*28 | Frame Shift Ins (INS) | VAF 108/260 reads (42%) | catalogued as rs748850271; called by mutect2, varscan2
- PHLPP2 | c.3485G>A p.G1162D | Missense Mutation (SNP) | VAF 246/480 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567610334, COSV62424416; called by muse, mutect2, varscan2
- PICK1 | c.42C>T p.L14= | Splice Region (SNP) | VAF 156/321 reads (49%) | catalogued as rs149993932; called by muse, mutect2, varscan2
- PIGS | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 183/380 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371227096; called by muse, mutect2, varscan2
- PIK3C2A | c.340del p.T114Hfs*10 | Frame Shift Del (DEL) | VAF 178/463 reads (38%) | catalogued as COSV56402935; called by mutect2, pindel, varscan2
- PIK3R2 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 343/621 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.587); catalogued as rs1365373370; called by muse, mutect2, varscan2
- PIK3R3 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 138/302 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs554826078, COSV53111455; called by muse, mutect2, varscan2
- PKD2 | c.1804A>G p.I602V | Missense Mutation (SNP) | VAF 234/480 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as rs763864486; called by muse, mutect2, varscan2
- PKP3 | c.1390dup p.L464Pfs*224 | Frame Shift Ins (INS) | VAF 302/634 reads (48%) | catalogued as rs757594408; called by mutect2, varscan2
- PLCD4 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 150/309 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs200972923; called by muse, mutect2, varscan2
- PLEC | c.9472C>T p.R3158W (on ENST00000322810 / NM_201380.4; = p.R3048W on NM_000445.5) | Missense Mutation (SNP) | VAF 290/921 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); catalogued as rs782202018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.4567G>A p.A1523T (on ENST00000322810 / NM_201380.4; = p.A1413T on NM_000445.5) | Missense Mutation (SNP) | VAF 370/1194 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as rs1554704033; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 142/310 reads (46%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHG2 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 199/403 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs766042286, COSV52678471; called by muse, mutect2, varscan2
- PLK1 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 260/527 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs751350031, COSV55621304; called by muse, varscan2
- PLXNB2 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 265/529 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as rs766018907, COSV63784396; called by muse, mutect2, varscan2
- POLR3D | c.553T>C p.S185P | Missense Mutation (SNP) | VAF 158/588 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs752293727; called by muse, mutect2, varscan2
- POLRMT | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 334/731 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775969994; called by muse, mutect2, varscan2
- POM121C | c.3475G>A p.A1159T (on ENST00000607367; = p.A917T on NM_001099415.3) | Missense Mutation (SNP) | VAF 165/387 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1335997342; called by muse, mutect2, varscan2
- POTEE | c.2057del p.K686Rfs*6 | Frame Shift Del (DEL) | VAF 290/476 reads (61%) | catalogued as rs772047281; called by mutect2, varscan2
- POTEF | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 124/1232 reads (10%) | catalogued as COSV62541836; called by mutect2, pindel
- POU5F1 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 168/623 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as rs1207558407; called by muse, mutect2, varscan2
- PPIL2 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 157/368 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs201283292, COSV58604804; called by muse, mutect2, varscan2
- PPM1E | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 207/479 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57578886; called by muse, mutect2, varscan2
- PPP1R32 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 268/551 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs778600925; called by muse, mutect2
- PPP1R9A | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 189/366 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748503389, COSV56895023; called by muse, mutect2, varscan2
- PPP2R5D | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 230/689 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs747480052, COSV99775928; called by muse, mutect2, varscan2
- PPP3R1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 113/225 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1260240599; called by muse, mutect2, varscan2
- PPRC1 | c.4382dup p.H1462Tfs*10 | Frame Shift Ins (INS) | VAF 171/376 reads (45%) | catalogued as rs772864639; called by mutect2, varscan2
- PRDM13 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 125/412 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760085132, COSV100980585, COSV65030985; called by muse, mutect2, varscan2
- PRDM13 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 253/812 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs1316332637; called by muse, mutect2, varscan2
- PRKDC | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 103/347 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100042784; called by muse, mutect2, varscan2
- PRLHR | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 460/805 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750948366, COSV53302690; called by muse, mutect2, varscan2
- PRMT1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 184/411 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV99773700; called by muse, mutect2, varscan2
- PRPF40A | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 126/309 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as rs760056687; called by muse, varscan2
- PRR19 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 358/760 reads (47%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.563); catalogued as COSV100003800; called by muse, mutect2, varscan2
- PRUNE2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 137/284 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs745462357, COSV100943317; called by muse, mutect2, varscan2
- PSKH2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 319/1010 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs750519355, COSV52609849; called by muse, mutect2, varscan2
- PSMD4 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 149/341 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.482); catalogued as rs930825880; called by muse, mutect2, varscan2
- PSMG1 | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 201/411 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs202176293; called by muse, mutect2, varscan2
- PTCH1 | c.196T>G p.S66A | Missense Mutation (SNP) | VAF 205/415 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100108463; called by muse, mutect2, varscan2
- PTK7 | c.2323G>A p.G775S | Missense Mutation (SNP) | VAF 264/853 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs750381359; called by muse, mutect2, varscan2
- PTMS | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 210/433 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs867073491; called by muse, mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 148/312 reads (47%) | catalogued as rs778292578; called by mutect2, varscan2
- PTPRT | c.904del p.A302Pfs*21 | Frame Shift Del (DEL) | VAF 201/536 reads (38%) | catalogued as COSV62008630; called by pindel, varscan2
- PVRIG | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 343/638 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52780877; called by muse, mutect2, varscan2
- PXDN | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 322/671 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53227915; called by muse, varscan2
- PXN | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 267/535 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs201921559, COSV57221596; called by muse, mutect2, varscan2
- QARS1 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 186/418 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs764216449, COSV60275524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- QSOX1 | c.1438A>G p.S480G | Missense Mutation (SNP) | VAF 246/474 reads (52%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.867); catalogued as rs1013295287; called by muse, mutect2, varscan2
- RAD18 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 169/323 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as rs781347031, COSV53749356; called by muse, mutect2, varscan2
- RANBP2 | c.7265G>A p.R2422H | Missense Mutation (SNP) | VAF 312/722 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51696555; called by muse, mutect2, varscan2
- RANBP9 | c.926C>A p.P309Q | Missense Mutation (SNP) | VAF 78/276 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50585009; called by muse, varscan2
- RAPGEF4 | c.2538del p.K846Nfs*5 | Frame Shift Del (DEL) | VAF 130/315 reads (41%) | catalogued as COSV51380239; called by mutect2, pindel, varscan2
- RAPGEFL1 | c.355C>G p.P119A | Missense Mutation (SNP) | VAF 343/693 reads (49%) | SIFT tolerated (1); PolyPhen probably damaging (0.911); catalogued as rs1034804333; called by muse, mutect2, varscan2
- RBM10 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 320/320 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100237976; called by muse, mutect2, varscan2
- RBM12B | c.1706del p.P569Rfs*91 | Frame Shift Del (DEL) | VAF 171/688 reads (25%) | catalogued as COSV101234463; called by mutect2, pindel, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 155/317 reads (49%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBSN | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 296/600 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773052562, COSV53794840; called by muse, mutect2, varscan2
- REEP3 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs747010885, COSV53424789; called by muse, mutect2, varscan2
- RERG | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 277/543 reads (51%) | catalogued as COSV99917223; called by muse, mutect2, varscan2
- REXO4 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 257/565 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs782112282; called by muse, mutect2, varscan2
- RGS14 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 227/477 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101281700; called by muse, mutect2, varscan2
- RIMS2 | c.1875del p.G626Efs*3 (on ENST00000666250 / NM_001348490.2; = p.G434Efs*3 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 312/591 reads (53%) | catalogued as rs1282720554; called by mutect2, pindel, varscan2
- RIN1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 268/593 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs533409856, COSV60925454; called by muse, mutect2, varscan2
- RIPK4 | c.1321C>T p.R441W (on ENST00000352483; = p.R393W on NM_020639.3) | Missense Mutation (SNP) | VAF 176/368 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs141192148; called by muse, mutect2, varscan2
- RMDN2 | c.976del p.M326Wfs*39 (on ENST00000354545 / NM_001322212.2; = p.M504Wfs*39 on NM_144713.5) | Frame Shift Del (DEL) | VAF 170/376 reads (45%) | catalogued as rs770517879; called by mutect2, pindel, varscan2
- RMDN3 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 252/536 reads (47%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.01); catalogued as rs370466451; called by muse, mutect2, varscan2
- ROBO4 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 312/636 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as rs748266690; called by muse, mutect2, varscan2
- ROCK2 | c.980del p.N327Ifs*7 | Frame Shift Del (DEL) | VAF 125/330 reads (38%) | catalogued as COSV55077330; called by mutect2, pindel, varscan2
- RP1L1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 262/888 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as rs900593447, COSV66754572; called by muse, varscan2
- RPL10L | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 254/490 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs764186971, COSV100022301; called by muse, varscan2
- RPL27A | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 174/412 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs562282613; called by muse, mutect2
- RPL7 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 152/485 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs976896432; called by muse, mutect2, varscan2
- RPRD1A | c.799del p.R267Afs*3 | Frame Shift Del (DEL) | VAF 111/278 reads (40%) | catalogued as COSV100442356; called by mutect2, pindel*, varscan2
- RREB1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 194/665 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs1418970900; called by muse, mutect2, varscan2
- RREB1 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 66/1294 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.227); catalogued as rs1561795961; called by muse, mutect2
- RREB1 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 287/842 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.27); catalogued as rs754945001, COSV100619301; called by muse, mutect2, varscan2
- RREB1 | c.4678C>T p.R1560W | Missense Mutation (SNP) | VAF 247/786 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748378386; called by muse, mutect2, varscan2
- RSRC2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 198/443 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs370217351; called by muse, mutect2, varscan2
- RTCB | c.444del p.F148Lfs*16 | Frame Shift Del (DEL) | VAF 209/556 reads (38%) | catalogued as COSV53279021; called by mutect2, pindel, varscan2
- RUNDC3B | c.23del p.G8Afs*2 | Frame Shift Del (DEL) | VAF 195/485 reads (40%) | catalogued as rs1554445885; called by mutect2, pindel, varscan2
- RYR2 | c.4546G>A p.G1516R | Missense Mutation (SNP) | VAF 232/482 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287904079, COSV63689022; called by muse, mutect2, varscan2
- SAFB2 | c.2194T>C p.Y732H | Missense Mutation (SNP) | VAF 216/466 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs1225396177; called by muse, mutect2, varscan2
- SAMD4B | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 361/712 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.147); catalogued as rs758480676; called by muse, mutect2, varscan2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 178/362 reads (49%) | catalogued as COSV59083791; called by mutect2, varscan2
- SARDH | c.568_569del p.L190Vfs*43 | Frame Shift Del (DEL) | VAF 264/671 reads (39%) | catalogued as rs1452007530; called by pindel, varscan2
- SCN5A | c.5756G>A p.R1919H (on ENST00000333535 / NM_198056.3; = p.R1918H on NM_000335.5) | Missense Mutation (SNP) | VAF 338/656 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs141107387; called by muse, mutect2, varscan2
- SCRIB | c.3876G>A p.M1292I | Missense Mutation (SNP) | VAF 295/965 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as rs942429013; called by muse, mutect2, varscan2
- SDC3 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 329/708 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as rs201140173, COSV100232519; called by muse, mutect2, varscan2
- SDHB | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM094748; called by muse, mutect2
- SDR16C5 | c.398A>G p.K133R | Missense Mutation (SNP) | VAF 199/636 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1211979027; called by muse, mutect2, varscan2
- SECISBP2L | c.2149C>T p.R717* (on ENST00000559471 / NM_001193489.2; = p.R672* on NM_014701.4) | Nonsense Mutation (SNP) | VAF 158/357 reads (44%) | catalogued as rs1269356789; called by muse, mutect2, varscan2
- SEL1L | c.1110del p.G371Vfs*20 | Frame Shift Del (DEL) | VAF 153/365 reads (42%) | catalogued as COSV60921783; called by mutect2, pindel, varscan2
- SEMA3A | c.1227G>A p.M409I | Missense Mutation (SNP) | VAF 158/331 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV54880077; called by muse, varscan2
- SEMA3G | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 329/635 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs541950335; called by muse, mutect2, varscan2
- SEMA4A | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 206/458 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.241); catalogued as COSV61772407; called by muse, mutect2, varscan2
- SEMA4F | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 105/585 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1275571318; called by muse, mutect2, varscan2
- SEMA6A | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 241/522 reads (46%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.793); catalogued as rs754006049; called by muse, mutect2, varscan2
- SERTAD1 | c.113del p.P38Rfs*34 | Frame Shift Del (DEL) | VAF 244/630 reads (39%) | catalogued as COSV100781697; called by mutect2, pindel, varscan2
- SETD1A | c.4838G>A p.R1613H | Missense Mutation (SNP) | VAF 55/427 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs765554192, COSV52679658; called by muse, mutect2, varscan2
- SF3B6 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 19/630 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV51981981; called by muse, mutect2
- SGIP1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 248/491 reads (51%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.166); catalogued as rs143844959; called by muse, mutect2, varscan2
- SGK3 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 139/415 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs753691709; called by muse, mutect2, varscan2
- SH3GL1 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 17/489 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53656433; called by muse, mutect2
- SH3RF1 | c.1904C>A p.P635H | Missense Mutation (SNP) | VAF 320/652 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.293); catalogued as COSV52921266; called by muse, mutect2, varscan2
- SH3RF3 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 374/742 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs373580159; called by muse, varscan2
- SHANK1 | c.6272G>A p.G2091D | Missense Mutation (SNP) | VAF 309/681 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV99521610; called by muse, mutect2, varscan2
- SHANK1 | c.1266del p.P424Qfs*5 | Frame Shift Del (DEL) | VAF 313/707 reads (44%) | catalogued as rs1568442066; called by mutect2, pindel, varscan2
- SHROOM1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 337/1190 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs1369747297; called by muse, mutect2, varscan2
- SIPA1L2 | c.4751G>A p.R1584Q | Missense Mutation (SNP) | VAF 172/343 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs760457506; called by muse, mutect2, varscan2
- SIPA1L3 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 377/735 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs148442622; called by muse, mutect2, varscan2
- SLC1A6 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 278/556 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.375); catalogued as rs149934975; called by muse, varscan2
- SLC22A13 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 222/424 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751044530, COSV100314450; called by muse, mutect2, varscan2
- SLC2A10 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 340/674 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753280877; ClinVar: uncertain significance; called by muse, varscan2
- SLC2A5 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 255/509 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142118350; called by muse, mutect2, varscan2
- SLC40A1 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 264/556 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs752593581, COSV53725387; called by muse, mutect2
- SLC46A3 | c.926del p.L309* | Frame Shift Del (DEL) | VAF 112/278 reads (40%) | catalogued as COSV99906530; called by mutect2, pindel, varscan2
- SLC4A10 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 123/261 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.356); catalogued as rs1365933953, COSV55783084; called by muse, mutect2, varscan2
- SLC6A12 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 280/583 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs779060532, COSV62885322; called by muse, mutect2, varscan2
- SLC6A15 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 216/413 reads (52%) | catalogued as rs1425540176, COSV99880203; called by muse, mutect2, varscan2
- SLC9B1 | c.1354C>A p.L452I | Missense Mutation (SNP) | VAF 56/310 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99599059; called by muse, mutect2, varscan2
- SLCO1B3 | c.833del p.F278Sfs*22 | Frame Shift Del (DEL) | VAF 98/269 reads (36%) | catalogued as rs751405974; called by mutect2, varscan2
- SMARCC1 | c.783del p.K261Nfs*7 | Frame Shift Del (DEL) | VAF 136/314 reads (43%) | catalogued as COSV99592634; called by mutect2, pindel, varscan2
- SMC6 | c.2974C>T p.R992C | Missense Mutation (SNP) | VAF 228/489 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1449974269; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 121/280 reads (43%) | catalogued as rs760667210; called by mutect2, varscan2
- SMCHD1 | c.3999del p.F1333Lfs*20 | Frame Shift Del (DEL) | VAF 169/435 reads (39%) | catalogued as rs1172818643; called by mutect2, pindel, varscan2
- SMPD3 | c.1557C>T p.D519= | Splice Region (SNP) | VAF 219/411 reads (53%) | catalogued as rs754364318; called by muse, mutect2, varscan2
- SNRNP48 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 193/558 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs778128352, COSV100672887; called by muse, mutect2, varscan2
- SNX13 | c.2148G>T p.E716D | Missense Mutation (SNP) | VAF 225/472 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.07); catalogued as COSV68066853; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 172/356 reads (48%) | catalogued as rs768873484; called by mutect2, varscan2
- SORCS1 | c.2233G>T p.A745S | Missense Mutation (SNP) | VAF 270/529 reads (51%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.52); catalogued as COSV53913466; called by muse, mutect2, varscan2
- SORL1 | c.2945G>A p.S982N | Missense Mutation (SNP) | VAF 163/377 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.396); catalogued as COSV52764773; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 365/1300 reads (28%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SPATA20 | c.1672G>A p.G558S (on ENST00000356488 / NM_001258372.1; = p.G574S on NM_022827.4) | Missense Mutation (SNP) | VAF 178/395 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs1459622290, COSV50065907; called by muse, mutect2, varscan2
- SPATA31D1 | c.425A>G p.Q142R | Missense Mutation (SNP) | VAF 142/814 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375482322; called by muse, mutect2
- SPHKAP | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 208/443 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780312968, COSV60888486; called by muse, mutect2, varscan2
- SPSB2 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 346/684 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1555133744, COSV51289986; called by muse, mutect2, varscan2
- SPTB | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 215/488 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs1009915997, COSV67629973; called by muse, mutect2, varscan2
- SPTBN5 | c.6412G>A p.A2138T | Missense Mutation (SNP) | VAF 248/556 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1318265278; called by muse, mutect2, varscan2
- SRRM2 | c.7602_7604del p.S2556del | In Frame Del (DEL) | VAF 206/537 reads (38%) | catalogued as rs746632079; called by pindel, varscan2
- SRRM4 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs189389386, COSV99939707; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214dup p.F407Lfs*55 | Frame Shift Ins (INS) | VAF 180/415 reads (43%) | catalogued as rs752994755; called by mutect2, varscan2
- STT3A | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 182/363 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as rs1383636042, COSV101205096, COSV104429732; called by muse, varscan2
- STX8 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 139/329 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as rs755945693, COSV100111002, COSV60488456; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 110/258 reads (43%) | catalogued as rs747003550; called by mutect2, varscan2
- SUSD2 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 423/824 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as rs778008563; called by muse, mutect2, varscan2
- SYBU | c.1586T>C p.M529T (on ENST00000276646 / NM_001099754.2; = p.M528T on NM_017786.6) | Missense Mutation (SNP) | VAF 255/773 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1261724854, COSV52621814; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 150/316 reads (47%) | catalogued as rs753462162; called by mutect2, varscan2
- SYNCRIP | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 236/728 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs759373270, COSV62288495; called by muse, varscan2
- TAAR1 | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 181/559 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1237178598; called by muse, mutect2, varscan2
- TAB2 | c.2027del p.L676* | Frame Shift Del (DEL) | VAF 235/805 reads (29%) | catalogued as rs749262561; called by mutect2, pindel, varscan2
- TAF11L13 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 303/652 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1215418381, COSV72825734; called by muse, mutect2, varscan2
- TARS2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 175/360 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs370560290; called by muse, mutect2, varscan2
- TBX22 | c.1143G>C p.W381C | Missense Mutation (SNP) | VAF 15/422 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as rs1014775367; called by muse, mutect2
- TBXAS1 | c.1571del p.N524Mfs*29 | Frame Shift Del (DEL) | VAF 182/430 reads (42%) | catalogued as rs748691839; called by mutect2, pindel, varscan2
- TCERG1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 304/966 reads (31%) | catalogued as COSV99695402; called by muse, mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 171/353 reads (48%) | catalogued as rs748021112; called by mutect2, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 215/428 reads (50%) | catalogued as COSV61906772; called by mutect2, varscan2
- TCHH | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 307/612 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV64275207; called by muse, mutect2, varscan2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 122/256 reads (48%) | catalogued as rs763438715; called by mutect2, varscan2
- TCN2 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 193/440 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs560678006; called by muse, mutect2, varscan2
- TCTE1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 291/869 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs533816994; called by muse, mutect2, varscan2
- TDRD12 | c.1790del p.N597Ifs*25 | Frame Shift Del (DEL) | VAF 144/282 reads (51%) | catalogued as rs1052864503; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 198/383 reads (52%) | catalogued as rs763321097; called by mutect2, varscan2
- TEX15 | c.3018del p.A1007Lfs*12 (on ENST00000256246; = p.A1390Lfs*12 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 174/617 reads (28%) | catalogued as rs753315680; called by mutect2, pindel, varscan2
- TFDP2 | c.463G>A p.A155T (on ENST00000489671 / NM_001178139.2; = p.A94T on NM_006286.5) | Missense Mutation (SNP) | VAF 196/447 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1251458626; called by muse, mutect2, varscan2
- TGFBR1 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 176/342 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66625243, COSV66627439; called by muse, mutect2, varscan2
- THAP7 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 314/637 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as rs1445240365, COSV53145551; called by muse, mutect2
- THBS2 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 220/731 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781465215; called by muse, mutect2, varscan2
- THBS4 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 221/474 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs367686922; called by muse, mutect2, varscan2
- TIMM29 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 28/530 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99450381; called by muse, mutect2
- TLN1 | c.4903G>A p.G1635S | Missense Mutation (SNP) | VAF 287/580 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as rs749077133; called by muse, mutect2, varscan2
- TLX1 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 24/664 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV64622355; called by muse, mutect2
- TMEM18 | c.421T>C p.*141Rext*42 | Nonstop Mutation (SNP) | VAF 151/325 reads (46%) | catalogued as COSV55243281; called by muse, mutect2, varscan2
- TMEM181 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 104/590 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as rs372660843; called by muse, mutect2, varscan2
- TMEM198 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 179/359 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.029); catalogued as rs1473056656; called by muse, mutect2, varscan2
- TMEM63B | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 218/742 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs751719789; called by muse, mutect2, varscan2
- TMTC1 | c.1058G>A p.R353Q (on ENST00000539277 / NM_001193451.2; = p.R245Q on NM_175861.3) | Missense Mutation (SNP) | VAF 174/379 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375595309; called by muse, mutect2, varscan2
- TNFRSF17 | c.440C>A p.P147Q | Missense Mutation (SNP) | VAF 18/626 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50000035; called by muse, mutect2
- TNFRSF9 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 211/470 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs748890197, COSV66349098; called by muse, mutect2, varscan2
- TNFRSF9 | c.345del p.G116Vfs*33 | Frame Shift Del (DEL) | VAF 101/278 reads (36%) | catalogued as rs752649731; called by mutect2, pindel, varscan2
- TNKS1BP1 | c.3656dup p.I1220Nfs*11 | Frame Shift Ins (INS) | VAF 282/793 reads (36%) | catalogued as rs1565040520; called by pindel, varscan2
- TNMD | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 258/259 reads (100%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs150078800; called by muse, mutect2, varscan2
- TNPO2 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 300/600 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as rs778630699, COSV63507859; called by muse, varscan2
- TNS1 | c.3011G>A p.R1004Q | Missense Mutation (SNP) | VAF 286/588 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs375058582, COSV99410363; called by muse, mutect2, varscan2
- TRAF7 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 297/542 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs766165474; called by muse, mutect2, varscan2
- TRAJ30 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 184/407 reads (45%) | catalogued as rs866941373; called by muse, varscan2
- TRAPPC9 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 272/837 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs769691517, COSV66907020; called by muse, mutect2, varscan2
- TRIM45 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 203/402 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs533016681, COSV56712893; called by muse, varscan2
- TRIM72 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 420/833 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.568); catalogued as COSV59067363; called by muse, mutect2, varscan2
- TRIR | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 199/405 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as rs1486166952; called by muse, mutect2, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 74/146 reads (51%) | catalogued as rs780358338; called by mutect2, varscan2
- TRPC1 | c.1506del p.F502Lfs*7 (on ENST00000476941 / NM_001251845.2; = p.F468Lfs*7 on NM_003304.4) | Frame Shift Del (DEL) | VAF 201/524 reads (38%) | catalogued as COSV56422836; called by mutect2, pindel, varscan2
- TSC1 | c.3209C>T p.A1070V | Missense Mutation (SNP) | VAF 272/568 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs1060503200, COSV53768377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSC22D4 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 438/931 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.976); catalogued as rs374915525; called by muse, mutect2, varscan2
- TSPYL2 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs374502411; called by muse, mutect2, varscan2
- TTC3 | c.1769del p.N590Tfs*4 | Frame Shift Del (DEL) | VAF 100/204 reads (49%) | catalogued as rs752525442; called by mutect2, varscan2
- TTC33 | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 262/492 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61802319, COSV61802560; called by muse, mutect2, varscan2
- TTC34 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 357/769 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1257455325; called by muse, mutect2, varscan2
- TTF1 | c.668del p.K223Rfs*45 | Frame Shift Del (DEL) | VAF 214/452 reads (47%) | catalogued as rs765042099; called by mutect2, varscan2
- TTK | c.484del p.S162Vfs*9 | Frame Shift Del (DEL) | VAF 88/307 reads (29%) | catalogued as rs751135082; called by mutect2, pindel, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 84/286 reads (29%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL10 | c.361C>T p.R121W (on ENST00000379289 / NM_001130045.2; = p.R48W on NM_153254.3) | Missense Mutation (SNP) | VAF 379/794 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as COSV101016876; called by muse, varscan2
- TTLL13P | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 282/558 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs371974190; called by muse, mutect2, varscan2
- TUBA3E | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 222/509 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as rs751114501; called by muse, mutect2, varscan2
- TUT4 | c.4720C>T p.R1574* | Nonsense Mutation (SNP) | VAF 137/284 reads (48%) | catalogued as COSV57115535; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 276/284 reads (97%) | catalogued as rs760251146; called by mutect2, varscan2
- UAP1 | c.619A>G p.K207E | Missense Mutation (SNP) | VAF 127/283 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs1458938846; called by muse, mutect2, varscan2
- UBR3 | c.3452G>A p.R1151H | Missense Mutation (SNP) | VAF 203/404 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs748028932, COSV55847157; called by muse, mutect2, varscan2
- UBR4 | c.13142C>T p.P4381L | Missense Mutation (SNP) | VAF 278/594 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs144615268; called by muse, mutect2, varscan2
- UBXN6 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 267/546 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs563472721, COSV56673428; called by muse, mutect2, varscan2
- USP13 | c.1854del p.L619Yfs*15 | Frame Shift Del (DEL) | VAF 165/411 reads (40%) | catalogued as rs1333558391; called by mutect2, pindel, varscan2
- USP19 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 202/409 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752502439, COSV60045903; called by muse, mutect2, varscan2
- VASN | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 473/950 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs750677669; called by muse, mutect2
- VCL | c.2906C>T p.A969V | Missense Mutation (SNP) | VAF 202/440 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs534101808, COSV53014542; called by muse, mutect2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 184/327 reads (56%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS13B | c.2879T>C p.L960S | Missense Mutation (SNP) | VAF 224/657 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs775378782; called by muse, mutect2, varscan2
- VPS13D | c.12743C>T p.A4248V | Missense Mutation (SNP) | VAF 161/341 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779850187, COSV50621319; called by muse, mutect2, varscan2
- VPS35L | c.2162G>A p.R721H | Missense Mutation (SNP) | VAF 174/380 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs770474820, COSV99221116; called by muse, mutect2, varscan2
- VSNL1 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 240/466 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs1260171799, COSV54597194; called by muse, mutect2, varscan2
- VWA1 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1463298717; called by muse, mutect2, varscan2
- VWA5B2 | c.731dup p.H245Sfs*19 | Frame Shift Ins (INS) | VAF 234/459 reads (51%) | catalogued as rs770124856; called by mutect2, varscan2
- WDR27 | c.1849dup p.A617Gfs*14 | Frame Shift Ins (INS) | VAF 168/634 reads (26%) | catalogued as rs768578801; called by mutect2, pindel, varscan2
- WDR33 | c.3457C>T p.R1153W | Missense Mutation (SNP) | VAF 174/374 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as rs552443294; called by muse, mutect2, varscan2
- WDR59 | c.2688C>T p.I896= | Splice Region (SNP) | VAF 165/326 reads (51%) | catalogued as rs147964482; called by muse, mutect2, varscan2
- WDR81 | c.4094T>C p.L1365P (on ENST00000409644 / NM_001163809.2; = p.L314P on NM_152348.4) | Missense Mutation (SNP) | VAF 457/906 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1156288032; called by muse, mutect2, varscan2
- WDR87 | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 261/550 reads (47%) | catalogued as rs868393245; called by muse, mutect2, varscan2
1,423 further variants in this file (856 protein-altering or splice-affecting, 485 silent, 82 other) are not listed here.
